Somatic mutation profile of tumor specimen TCGA-66-2758-01A (aliquot TCGA-66-2758-01A-02D-1522-08) from TCGA case TCGA-66-2758, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 71.8 years (26,209 days).
Specimen TCGA-66-2758-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 455d4905-26d4-411e-9f2b-5c96a2d6145d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-66-2758-11A (Solid Tissue Normal), aliquot TCGA-66-2758-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/778ba8fe-8d7c-4655-a939-af1d9a60788e

The open-access MAF lists 359 somatic variants for this specimen: 260 protein-altering or splice-affecting, 87 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 222, Silent 87, Nonsense Mutation 13, Frame Shift Del 8, In Frame Del 8, Intron 6, Splice Site 3, RNA 3, Translation Start Site 2, Frame Shift Ins 2, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 18/71 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs104894226, CM053285, COSV54237021, COSV54237051; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.373A>C p.T125P | Missense Mutation (SNP) | VAF 59/112 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057520003, CM156966, COSV52780750, COSV52951418, COSV53606217; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TTN | c.58102C>T p.R19368* (on ENST00000591111; = p.R11944* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 115/262 reads (44%) | catalogued as rs368452607, CM1514596, COSV60000901; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.760A>T p.I254F | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV50962393; called by muse, mutect2
- ABCA3 | c.1554C>G p.Y518* | Nonsense Mutation (SNP) | VAF 121/228 reads (53%) | catalogued as COSV57052448; called by muse, mutect2, varscan2
- ABCC9 | c.440C>T p.T147I | Missense Mutation (SNP) | VAF 166/363 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.374); catalogued as COSV53968887; called by muse, mutect2, varscan2
- ACOXL | c.1515G>C p.Q505H (on ENST00000389811 / NM_001371254.1; = p.Q475H on NM_001142807.4) | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); catalogued as COSV67735351; called by muse, mutect2, varscan2
- ACSL3 | c.1342C>G p.L448V | Missense Mutation (SNP) | VAF 87/150 reads (58%) | SIFT tolerated (0.43); PolyPhen benign (0.17); catalogued as COSV62481797; called by muse, mutect2, varscan2
- ACVR1C | c.701G>C p.R234P | Missense Mutation (SNP) | VAF 24/251 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54645613; called by muse, mutect2
- ADAM29 | c.1742G>T p.C581F | Missense Mutation (SNP) | VAF 84/234 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63662868; called by muse, mutect2, varscan2
- ADAMTS4 | c.1664G>T p.G555V | Missense Mutation (SNP) | VAF 58/395 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63489766; called by muse, mutect2, varscan2
- ADGRB2 | c.4032G>T p.E1344D | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV57072830; called by muse, mutect2, varscan2
- ADGRE1 | c.337T>C p.S113P | Missense Mutation (SNP) | VAF 66/147 reads (45%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.93); catalogued as COSV51674749; called by muse, mutect2, varscan2
- AFAP1L1 | c.2002G>T p.A668S | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as COSV57044863; called by muse, mutect2, varscan2
- AFMID | c.316G>T p.E106* | Nonsense Mutation (SNP) | VAF 33/102 reads (32%) | catalogued as COSV59975842; called by muse, mutect2, varscan2
- AGXT2 | c.565G>C p.D189H | Missense Mutation (SNP) | VAF 46/392 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV51485707; called by muse, mutect2, varscan2
- AKAP9 | c.9172T>C p.F3058L (on ENST00000359028; = p.F3034L on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 118/583 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.628); catalogued as COSV62343965; called by muse, mutect2, varscan2
- ANGPTL5 | c.655C>A p.L219I | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV57532720; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3500A>T p.Y1167F | Missense Mutation (SNP) | VAF 137/225 reads (61%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV51845400; called by muse, mutect2, varscan2
- ANKIB1 | c.1526G>T p.C509F | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); catalogued as COSV56060683; called by muse, mutect2, varscan2
- ANKS1B | c.939G>T p.E313D | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV61346988; called by muse, mutect2, varscan2
- ANO4 | c.44T>A p.V15D | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); catalogued as COSV54593246; called by muse, mutect2, varscan2
- ARFGEF1 | c.2516A>G p.H839R | Missense Mutation (SNP) | VAF 49/259 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51606873; called by muse, mutect2, varscan2
- ARHGAP36 | c.284A>G p.D95G | Missense Mutation (SNP) | VAF 169/235 reads (72%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV52265940; called by muse, mutect2, varscan2
- ARHGEF40 | c.595A>T p.S199C | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.417); catalogued as COSV53879745, COSV53885124; called by muse, mutect2, varscan2
- ARID5B | c.849G>A p.V283= | Splice Region (SNP) | VAF 29/62 reads (47%) | catalogued as COSV54418658; called by muse, varscan2
- ASH2L | c.748G>T p.D250Y | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV51699322, COSV99166927; called by muse, mutect2, varscan2
- BCL9L | c.3937G>T p.V1313L | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as rs760459717, COSV52683755; called by muse, mutect2, varscan2
- BDKRB1 | c.220A>G p.I74V | Missense Mutation (SNP) | VAF 62/106 reads (58%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.71); catalogued as COSV53705946; called by muse, mutect2, varscan2
- BIRC6 | c.7193C>A p.S2398Y | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV70198332; called by muse, mutect2, varscan2
- BTBD16 | c.1378G>C p.G460R | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs184112208, COSV53262339; called by muse, mutect2, varscan2
- C1orf131 | c.494A>G p.E165G | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59642193; called by muse, mutect2, varscan2
- CACNA1S | c.5261G>C p.R1754T | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.019); catalogued as COSV100755028, COSV62938793; called by muse, mutect2, varscan2
- CCDC9B | c.1523C>A p.T508K | Missense Mutation (SNP) | VAF 125/382 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs572485964, COSV66875213, COSV66875496; called by muse, mutect2, varscan2
- CCSER1 | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 56/110 reads (51%) | SIFT tolerated (0.3); PolyPhen benign (0.124); catalogued as COSV61424321; called by muse, mutect2, varscan2
- CD1E | c.980C>G p.S327* | Nonsense Mutation (SNP) | VAF 40/92 reads (43%) | catalogued as rs1394656791, COSV63769912, COSV63770792; called by muse, mutect2, varscan2
- CDH11 | c.1035G>C p.L345F | Missense Mutation (SNP) | VAF 55/120 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.113); catalogued as COSV51759121; called by muse, mutect2, varscan2
- CFAP58 | c.2128G>C p.V710L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.169); catalogued as COSV100866073, COSV63833793; called by muse, mutect2, varscan2
- CFAP61 | c.1683T>A p.F561L | Missense Mutation (SNP) | VAF 89/209 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as COSV55626686; called by muse, mutect2, varscan2
- CFC1 | c.240C>A p.F80L | Missense Mutation (SNP) | VAF 26/190 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV52090345, COSV52090471; called by muse, mutect2, varscan2
- CHD8 | c.1795G>A p.E599K (on ENST00000646647 / NM_001170629.2; = p.E320K on NM_020920.4) | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.074); catalogued as COSV67870281; called by muse, mutect2, varscan2
- CHERP | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.637); catalogued as COSV52223872; called by muse, mutect2, varscan2
- CKS1B | c.20A>G p.Y7C | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as COSV58316145; called by muse, mutect2, varscan2
- CLASP2 | c.3443A>G p.Y1148C (on ENST00000359576; = p.Y1147C on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV56280742; called by muse, mutect2, varscan2
- CMTR1 | c.398G>T p.R133L | Missense Mutation (SNP) | VAF 112/262 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV100990872; called by mutect2, varscan2
- CNGA1 | c.1330G>T p.V444F | Missense Mutation (SNP) | VAF 78/454 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as COSV62053981; called by muse, mutect2, varscan2
- CNTFR | c.739C>G p.R247G | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63633621; called by muse, mutect2, varscan2
- CNTN5 | c.2086G>A p.D696N | Missense Mutation (SNP) | VAF 64/117 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.911); catalogued as rs1209818461, COSV54303822; called by muse, mutect2, varscan2
- COL22A1 | c.1268T>C p.I423T | Missense Mutation (SNP) | VAF 87/208 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.188); catalogued as COSV57333346; called by muse, mutect2, varscan2
- CPAMD8 | c.1771T>G p.S591A (on ENST00000651564; = p.S544A on NM_015692.5) | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.992); catalogued as COSV52233515; called by muse, mutect2, varscan2
- CPZ | c.198G>T p.Q66H (on ENST00000360986 / NM_001014447.3; = p.Q55H on NM_003652.3) | Missense Mutation (SNP) | VAF 89/123 reads (72%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.485); catalogued as COSV59922660; called by muse, mutect2, varscan2
- CR1 | c.6052C>G p.Q2018E | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV65457614; called by muse, mutect2, varscan2
- CRNN | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 124/1024 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV55121660; called by muse, mutect2, varscan2
- CSGALNACT1 | c.624T>A p.D208E | Missense Mutation (SNP) | VAF 58/193 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as COSV59976567; called by muse, mutect2, varscan2
- CSMD3 | c.7676G>C p.G2559A (on ENST00000297405 / NM_001363185.1; = p.G2455A on NM_052900.3) | Missense Mutation (SNP) | VAF 66/198 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV52158781, COSV99821688; called by muse, mutect2, varscan2
- CUX1 | c.3433+1G>T p.X1145_splice | Splice Site (SNP) | VAF 14/116 reads (12%) | catalogued as COSV52897000; called by muse, varscan2
- DCDC1 | c.4021G>A p.G1341R (on ENST00000597505 / NM_001367979.1; = p.G448R on NM_020869.3) | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.31); catalogued as COSV100338087, COSV57998715; called by muse, mutect2, varscan2
- DDX56 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 61/274 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51835503; called by muse, mutect2, varscan2
- DEPTOR | c.482A>T p.Y161F | Missense Mutation (SNP) | VAF 83/188 reads (44%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.585); catalogued as COSV53815003; called by muse, mutect2, varscan2
- DIAPH2 | c.3238C>G p.P1080A | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT tolerated (0.78); PolyPhen benign (0.009); catalogued as rs1319243713, COSV61266542; called by muse, mutect2, varscan2
- DNAI1 | c.723G>C p.Q241H | Missense Mutation (SNP) | VAF 38/213 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as COSV54280472; called by muse, mutect2, varscan2
- DNAJC13 | c.4635G>T p.W1545C | Missense Mutation (SNP) | VAF 39/286 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53449295; called by muse, mutect2, varscan2
- DPP6 | c.33G>C p.K11N | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.95); catalogued as COSV68056449; called by muse, mutect2, varscan2
- DRICH1 | c.395C>A p.S132* | Nonsense Mutation (SNP) | VAF 52/275 reads (19%) | catalogued as COSV58503569; called by muse, mutect2, varscan2
- DYNLL2 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.072); catalogued as COSV73897025; called by muse, mutect2, varscan2
- EIF2B5 | c.567G>A p.M189I (on ENST00000647909; = p.M181I on NM_003907.3) | Missense Mutation (SNP) | VAF 28/233 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.919); catalogued as COSV56604337; called by muse, mutect2, varscan2
- EIF4G1 | c.571G>T p.D191Y | Missense Mutation (SNP) | VAF 16/263 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59990424; called by muse, mutect2
- EPHA10 | c.1598C>A p.S533Y | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs368330975, COSV57622095; called by muse, mutect2, varscan2
- FCER2 | c.442C>G p.L148V | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs147413598, COSV60916234; called by muse, mutect2, varscan2
- FHOD3 | c.2894G>C p.R965T (on ENST00000359247 / NM_001281739.3; = p.R982T on NM_025135.5) | Missense Mutation (SNP) | VAF 93/196 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57171320; called by muse, mutect2, varscan2
- FMO5 | c.718C>G p.L240V | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV54205806; called by muse, mutect2
- FOXK2 | c.1010C>A p.A337D | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.1); catalogued as COSV58878461; called by muse, mutect2, varscan2
- FOXRED2 | c.859G>C p.A287P | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.543); catalogued as COSV53399626; called by muse, mutect2, varscan2
- FUBP1 | c.142G>C p.D48H | Missense Mutation (SNP) | VAF 45/75 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV53929633; called by muse, mutect2, varscan2
- FUT10 | c.46G>T p.V16F | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV59451060; called by muse, mutect2, varscan2
- G6PC2 | c.590C>G p.P197R | Missense Mutation (SNP) | VAF 29/224 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as COSV56371978; called by muse, mutect2, varscan2
- GABRA4 | c.1646A>T p.K549I | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.039); catalogued as COSV51926285; called by muse, mutect2, varscan2
- GABRG1 | c.653A>G p.Y218C | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1237024046, COSV54952913; called by mutect2, varscan2
- GARRE1 | c.431T>A p.M144K | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.948); catalogued as COSV55098573; called by muse, mutect2
- GEMIN8 | c.318C>G p.I106M | Missense Mutation (SNP) | VAF 92/188 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV60550389; called by muse, mutect2, varscan2
- GOLGA6B | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 95/620 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as COSV69770078; called by muse, mutect2, varscan2
- GON4L | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 64/455 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs1008989857, COSV55192198; called by muse, mutect2, varscan2
- GPATCH8 | c.1651T>A p.W551R | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59194362; called by muse, mutect2, varscan2
- GPR174 | c.78C>G p.Y26* | Nonsense Mutation (SNP) | VAF 5/69 reads (7%) | catalogued as COSV52132151; called by muse, mutect2
- GRIK1 | c.2760G>C p.K920N (on ENST00000327783 / NM_001330994.2; = p.K876N on NM_175611.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/94 reads (56%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.206); catalogued as COSV100583324, COSV59864820, COSV59870415; called by muse, mutect2, varscan2
- GRPR | c.1100C>G p.S367C | Missense Mutation (SNP) | VAF 81/177 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs1226925757, COSV66669148, COSV66669197; called by muse, mutect2, varscan2
- H2AC17 | c.154C>G p.L52V | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.731); catalogued as COSV58152477; called by muse, mutect2, varscan2
- HIGD1B | c.101-1G>A p.X34_splice | Splice Site (SNP) | VAF 20/150 reads (13%) | catalogued as rs1160210617, COSV53655473; called by muse, mutect2, varscan2
- HYDIN | c.9320G>T p.G3107V | Missense Mutation (SNP) | VAF 65/125 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59255190; called by muse, mutect2, varscan2
- IFNA13 | c.202G>C p.D68H | Missense Mutation (SNP) | VAF 59/146 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as COSV71924461, COSV71924490; called by muse, mutect2, varscan2
- ING3 | c.368C>A p.S123Y | Missense Mutation (SNP) | VAF 42/349 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV59950794; called by muse, mutect2, varscan2
- ISM2 | c.996G>C p.W332C (on ENST00000342219 / NM_199296.3; = p.G217A on NM_182509.4) | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53634691; called by muse, mutect2, varscan2
- ITPKC | c.1089C>G p.F363L | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.883); catalogued as COSV54574293; called by muse, mutect2, varscan2
- ITPKC | c.1987G>A p.E663K | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54574303, COSV99648935; called by muse, mutect2, varscan2
- KCNA1 | c.310A>T p.R104W | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66837096; called by muse, mutect2, varscan2
- KCND1 | c.469G>A p.G157R | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as rs147309267, COSV54413677; called by muse, mutect2, varscan2
- KIAA1191 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 47/206 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as COSV53798789; called by muse, mutect2, varscan2
- KIF2A | c.2048C>G p.S683C | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.619); catalogued as COSV52232746, COSV52233522; called by muse, mutect2
- KIFC2 | c.427G>T p.G143W | Missense Mutation (SNP) | VAF 82/245 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.841); catalogued as COSV56760834; called by muse, mutect2, varscan2
- KRT14 | c.433G>C p.V145L | Missense Mutation (SNP) | VAF 118/367 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.06); catalogued as COSV51421062; called by muse, mutect2, varscan2
- KRT82 | c.686T>C p.V229A | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV57785847; called by muse, mutect2, varscan2
- LMOD1 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66172496; called by muse, mutect2, varscan2
- LRP1B | c.10982G>T p.G3661V | Missense Mutation (SNP) | VAF 59/401 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV67208450; called by muse, mutect2, varscan2
- LRP1B | c.10981G>C p.G3661R | Missense Mutation (SNP) | VAF 57/398 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.533); catalogued as COSV67208454; called by muse, mutect2, varscan2
- LRP1B | c.9107C>A p.T3036K | Missense Mutation (SNP) | VAF 32/249 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs757186045, COSV67208459; called by muse, mutect2, varscan2
- LTBP4 | c.3376G>A p.D1126N (on ENST00000308370 / NM_001042544.1; = p.D1089N on NM_003573.2) | Missense Mutation (SNP) | VAF 69/187 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV52580245, COSV52590948; called by muse, mutect2, varscan2
- LY75 | c.428G>A p.G143E | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV55104644; called by muse, varscan2
- LY75 | c.283C>A p.L95M | Missense Mutation (SNP) | VAF 70/152 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs747989584, COSV55104653; called by muse, varscan2
- MACF1 | c.14151C>G p.I4717M (on ENST00000372915; = p.I2650M on NM_012090.5) | Missense Mutation (SNP) | VAF 34/63 reads (54%) | catalogued as COSV57117979, COSV57133315; called by muse, mutect2, varscan2
- MASP1 | c.1723G>C p.E575Q | Missense Mutation (SNP) | VAF 81/438 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as COSV61825805; called by muse, mutect2, varscan2
- MCM3AP | c.705G>C p.K235N | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.915); catalogued as COSV52438899; called by muse, mutect2, varscan2
- MED7 | c.170G>C p.R57P | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.193); catalogued as COSV53850004; called by muse, mutect2, varscan2
- MLH3 | c.1469C>A p.S490Y | Missense Mutation (SNP) | VAF 114/212 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1017281490, COSV53153789, COSV99469879; called by muse, mutect2, varscan2
- MLNR | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 49/90 reads (54%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs574134980, COSV54531615; called by muse, mutect2, varscan2
- MMAA | c.1192A>C p.I398L | Missense Mutation (SNP) | VAF 39/167 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV55579791; called by muse, mutect2, varscan2
- MRPL1 | c.51G>T p.R17S | Missense Mutation (SNP) | VAF 58/211 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as COSV59674253; called by muse, mutect2, varscan2
- MRPL36 | c.128A>G p.E43G | Missense Mutation (SNP) | VAF 66/194 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV56876456; called by muse, mutect2, varscan2
- MRPS31 | c.300A>C p.L100F | Missense Mutation (SNP) | VAF 89/189 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.184); catalogued as COSV60266737; called by muse, mutect2, varscan2
- MS4A12 | c.559G>C p.G187R | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV50014335; called by muse, mutect2, varscan2
- MYCBP2 | c.6973A>G p.M2325V (on ENST00000357337; = p.M2363V on NM_015057.5) | Missense Mutation (SNP) | VAF 145/248 reads (58%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1157762530, COSV62016110; called by muse, mutect2, varscan2
- MYH6 | c.1743C>G p.I581M | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV62449618; called by muse, mutect2, varscan2
- MYPN | c.1577G>T p.S526I | Missense Mutation (SNP) | VAF 91/144 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62733254; called by muse, mutect2, varscan2
- MYT1L | c.1550G>T p.G517V | Missense Mutation (SNP) | VAF 114/294 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67717912; called by muse, mutect2, varscan2
- NEO1 | c.1969C>A p.P657T | Missense Mutation (SNP) | VAF 45/342 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56070206; called by muse, varscan2
- NIN | c.1922A>T p.D641V | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.296); catalogued as COSV55387747; called by muse, mutect2, varscan2
- NME8 | c.1153G>T p.A385S | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52249230; called by muse, mutect2, varscan2
- NOBOX | c.440C>G p.S147C | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as COSV56193829; called by muse, mutect2, varscan2
- NOP14 | c.1268C>G p.P423R | Missense Mutation (SNP) | VAF 102/325 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58625006; called by muse, mutect2, varscan2
- NOP56 | c.325G>C p.G109R | Missense Mutation (SNP) | VAF 50/260 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV61389690; called by muse, mutect2, varscan2
- OGDH | c.2435T>G p.L812R | Missense Mutation (SNP) | VAF 61/267 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.255); catalogued as COSV56048658; called by muse, mutect2, varscan2
- OR2F2 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 98/808 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68832720; called by muse, varscan2
- OR4A5 | c.551T>G p.L184R | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV60522291; called by muse, mutect2, varscan2
- OR5L2 | c.769T>C p.Y257H | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV65723807; called by muse, varscan2
- OR5T1 | c.769C>A p.L257I | Missense Mutation (SNP) | VAF 71/395 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV57302516; called by muse, mutect2, varscan2
- P2RX4 | c.1086G>C p.K362N | Missense Mutation (SNP) | VAF 200/481 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.332); catalogued as COSV61214203; called by muse, mutect2, varscan2
- PCDHB7 | c.1615C>A p.P539T | Missense Mutation (SNP) | VAF 68/110 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50762881; called by muse, mutect2, varscan2
- PCDHB8 | c.1540C>G p.L514V | Missense Mutation (SNP) | VAF 106/651 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as COSV50754678, COSV50762938; called by muse, mutect2, varscan2
- PCDHB8 | c.1739C>T p.A580V | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.073); catalogued as COSV50762943; called by mutect2, varscan2
- PGLYRP4 | c.203G>C p.C68S | Missense Mutation (SNP) | VAF 122/307 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62835090; called by muse, mutect2, varscan2
- PHACTR1 | c.1220G>T p.S407I | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.205); catalogued as COSV60664753; called by muse, varscan2
- PHF14 | c.1520A>G p.K507R | Missense Mutation (SNP) | VAF 52/237 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.045); catalogued as COSV68855058; called by muse, mutect2, varscan2
- PHKG1 | c.568T>A p.Y190N | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51916180; called by muse, mutect2, varscan2
- PHOX2B | c.223A>T p.S75C | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.889); catalogued as COSV56929295; called by muse, mutect2, varscan2
- PIGH | c.472C>T p.Q158* | Nonsense Mutation (SNP) | VAF 33/102 reads (32%) | catalogued as COSV53614388; called by muse, mutect2, varscan2
- PKHD1L1 | c.2106G>C p.Q702H | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.251); catalogued as COSV65741623, COSV65753297; called by muse, mutect2, varscan2
- PLCB2 | c.1134G>C p.M378I | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV53032806; called by muse, mutect2, varscan2
- PLEKHA5 | c.2336G>C p.R779T | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54698865; called by muse, mutect2, varscan2
- PLEKHN1 | c.1865G>A p.R622Q (on ENST00000379409; = p.R570Q on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs768957902, COSV58021620; called by muse, mutect2, varscan2
- PNPLA5 | c.666C>G p.F222L | Missense Mutation (SNP) | VAF 43/314 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs374016542; called by muse, mutect2, varscan2
- PODXL2 | c.717G>T p.M239I | Missense Mutation (SNP) | VAF 59/168 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV61065201; called by muse, mutect2, varscan2
- PRDM11 | c.1197G>A p.W399* (on ENST00000530656 / NM_001359633.1; = p.W365* on NM_001256695.1) | Nonsense Mutation (SNP) | VAF 77/229 reads (34%) | catalogued as COSV55439337; called by muse, mutect2, varscan2
- PRKAR1A | c.322G>T p.E108* | Nonsense Mutation (SNP) | VAF 57/167 reads (34%) | catalogued as COSV62235478; called by muse, mutect2, varscan2
- PROM2 | c.814A>G p.T272A | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.285); catalogued as rs768628476, COSV58297690; called by muse, mutect2, varscan2
- PRRC2B | c.3925A>C p.K1309Q | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61936164; called by muse, mutect2, varscan2
- PSMD7 | c.619G>C p.D207H | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as COSV54697510; called by muse, mutect2, varscan2
- PXYLP1 | c.493C>G p.L165V | Missense Mutation (SNP) | VAF 91/538 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53890080; called by muse, mutect2, varscan2
- RAB11B | c.480C>A p.N160K | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs770759610, COSV60085635, COSV60085782; called by muse, mutect2, varscan2
- RARA | c.322T>A p.C108S | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV54191606; called by muse, mutect2, varscan2
- RARS1 | c.1623C>G p.I541M | Missense Mutation (SNP) | VAF 61/353 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as COSV51563081; called by muse, mutect2, varscan2
- RIN3 | c.677C>T p.S226L | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as rs201944996, COSV53647530; called by muse, mutect2
- RTL6 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.542); catalogued as COSV57979533, COSV57979730; called by muse, mutect2, varscan2
- RTN4 | c.701C>G p.S234C | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV58266764; called by muse, mutect2, varscan2
- RUBCN | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 41/189 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV56365162; called by muse, mutect2, varscan2
- RXRG | c.712A>G p.R238G | Missense Mutation (SNP) | VAF 61/196 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV63231949; called by muse, mutect2, varscan2
- RYR3 | c.12440C>A p.S4147Y (on ENST00000389232; = p.S4148Y on NM_001036.6) | Missense Mutation (SNP) | VAF 63/150 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as COSV66785533; called by muse, mutect2, varscan2
- SCAF4 | c.1442G>T p.R481I | Missense Mutation (SNP) | VAF 52/153 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54586281; called by muse, mutect2, varscan2
- SCN5A | c.2894G>A p.R965H | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs199473181, CM067021, CM097656, COSV61121747; ClinVar: not provided / uncertain significance; called by muse, mutect2, varscan2
- SCRIB | c.4192C>T p.Q1398* | Nonsense Mutation (SNP) | VAF 10/22 reads (45%) | catalogued as COSV57585553; called by muse, mutect2, varscan2
- SEC24A | c.1450C>G p.Q484E | Missense Mutation (SNP) | VAF 106/163 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as COSV59746859; called by muse, mutect2, varscan2
- SEMA4C | c.1814A>G p.Y605C | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as rs891369753, COSV59690359; called by muse, mutect2, varscan2
- SEZ6 | c.526C>A p.P176T | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.177); catalogued as rs765736815, COSV57979118; called by muse, mutect2, varscan2
- SFTPA2 | c.419C>T p.S140F | Missense Mutation (SNP) | VAF 135/285 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV100958776; called by muse, mutect2, varscan2
- SH3PXD2B | c.1803G>T p.K601N | Missense Mutation (SNP) | VAF 93/148 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV61126307; called by muse, mutect2, varscan2
- SHROOM3 | c.4807A>T p.T1603S | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV56027672; called by muse, mutect2, varscan2
- SI | c.2236C>G p.L746V | Missense Mutation (SNP) | VAF 87/378 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as COSV52274794; called by muse, mutect2, varscan2
- SLC26A7 | c.1723G>T p.D575Y | Missense Mutation (SNP) | VAF 106/384 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV52591361; called by muse, mutect2, varscan2
- SLC6A4 | c.730G>T p.G244W | Missense Mutation (SNP) | VAF 76/231 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55566498; called by muse, mutect2, varscan2
- SLC6A4 | c.130T>C p.S44P | Missense Mutation (SNP) | VAF 125/371 reads (34%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.583); catalogued as COSV55566509; called by muse, mutect2, varscan2
- SLC9A5 | c.1928G>A p.R643Q | Missense Mutation (SNP) | VAF 46/66 reads (70%) | SIFT tolerated (0.07); PolyPhen benign (0.397); catalogued as rs769149966, COSV55361671; called by muse, mutect2, varscan2
- SLC9A9 | c.1893T>A p.Y631* | Nonsense Mutation (SNP) | VAF 69/207 reads (33%) | catalogued as rs1213323892, COSV57224941; called by muse, mutect2, varscan2
- SLCO1B1 | c.513G>C p.W171C | Missense Mutation (SNP) | VAF 21/259 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57009953, COSV57014552; called by muse, mutect2
- SLITRK3 | c.2621C>G p.P874R | Missense Mutation (SNP) | VAF 75/322 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.247); catalogued as COSV53847679; called by muse, mutect2, varscan2
- SLITRK5 | c.2303G>A p.R768Q | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.738); catalogued as rs1377185185, COSV61521019; called by muse, mutect2, varscan2
- SMAD7 | c.565G>T p.E189* | Nonsense Mutation (SNP) | VAF 13/31 reads (42%) | catalogued as COSV50989233; called by muse, mutect2, varscan2
- SNAPC4 | c.4388G>A p.R1463Q | Missense Mutation (SNP) | VAF 122/300 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs201999899; called by muse, varscan2
- SNRPB | c.535A>G p.M179V | Missense Mutation (SNP) | VAF 86/434 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.267); catalogued as rs770650165, COSV60015122; called by muse, varscan2
- SOGA1 | c.3475T>G p.L1159V | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as COSV52916913; called by muse, mutect2, varscan2
- SOWAHB | c.1925G>T p.G642V | Missense Mutation (SNP) | VAF 89/261 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57554342; called by muse, mutect2, varscan2
- SPIC | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as COSV54690925; called by muse, mutect2, varscan2
- SPIRE1 | c.1288G>A p.G430S (on ENST00000409402 / NM_001128626.2; = p.G416S on NM_020148.3) | Missense Mutation (SNP) | VAF 36/274 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100563936, COSV59155105; called by muse, mutect2, varscan2
- SRGAP1 | c.2660C>G p.P887R | Missense Mutation (SNP) | VAF 76/180 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.101); catalogued as COSV61896859; called by muse, mutect2, varscan2
- SRP54 | c.751G>C p.D251H | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV53739485; called by muse, mutect2, varscan2
- SS18 | c.644A>T p.Y215F | Missense Mutation (SNP) | VAF 48/343 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs1259644070, COSV52260636; called by muse, mutect2, varscan2
- ST6GAL1 | c.159A>T p.K53N | Missense Mutation (SNP) | VAF 62/570 reads (11%) | PolyPhen benign (0.014); catalogued as COSV51468828; called by muse, mutect2, varscan2
- STARD8 | c.1733T>C p.V578A | Missense Mutation (SNP) | VAF 12/12 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV52925132; called by muse, mutect2, varscan2
- STC2 | c.94G>C p.E32Q | Missense Mutation (SNP) | VAF 34/180 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.095); catalogued as COSV54179370; called by muse, mutect2, varscan2
- STK3 | c.1268A>G p.N423S | Missense Mutation (SNP) | VAF 81/174 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV69223083; called by muse, mutect2, varscan2
- STRIP2 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 91/598 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs746730562, COSV50803995; called by muse, mutect2, varscan2
- STRIP2 | c.2290_2292del p.E764del | In Frame Del (DEL) | VAF 50/134 reads (37%) | catalogued as rs760981516; called by pindel, varscan2
- TAL1 | c.480G>C p.M160I | Missense Mutation (SNP) | VAF 46/200 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV53746181; called by muse, mutect2, varscan2
- TBC1D25 | c.1105G>A p.D369N | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as COSV65123565; called by muse, mutect2, varscan2
- TET3 | c.491G>C p.G164A | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.664); catalogued as COSV59880713; called by muse, mutect2, varscan2
- TEX15 | c.74G>T p.S25I (on ENST00000256246; = p.S408I on NM_001350162.2) | Missense Mutation (SNP) | VAF 109/236 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV56345274; called by muse, mutect2, varscan2
- THAP11 | c.746C>G p.S249W | Missense Mutation (SNP) | VAF 86/491 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV54645780; called by muse, mutect2, varscan2
- THAP12 | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 30/143 reads (21%) | catalogued as COSV52610313; called by muse, mutect2, varscan2
- TMCC3 | c.755G>T p.G252V | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1451888005, COSV54153755; called by muse, mutect2, varscan2
- TMEM184B | c.761C>T p.S254F | Missense Mutation (SNP) | VAF 53/179 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as rs866271142, COSV62672382; called by muse, mutect2, varscan2
- TMEM26 | c.339G>C p.L113F | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.776); catalogued as COSV53261864, COSV53263633; called by muse, mutect2, varscan2
- TMPRSS12 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68256187; called by muse, mutect2, varscan2
- TNC | c.5691G>C p.E1897D | Missense Mutation (SNP) | VAF 43/224 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0.208); catalogued as COSV60783865; called by muse, mutect2, varscan2
- TNC | c.1298A>G p.D433G | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60783874; called by muse, mutect2
- TNR | c.3685G>T p.D1229Y | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54881180; called by muse, mutect2, varscan2
- TNRC6B | c.784G>T p.D262Y | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV57293743; called by muse, mutect2, varscan2
- TNS2 | c.439G>C p.A147P (on ENST00000314250 / NM_170754.4; = p.A157P on NM_015319.2) | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs552336137, COSV58576759; called by muse, mutect2, varscan2
- TPP1 | c.166C>A p.Q56K | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as COSV54997048; called by muse, mutect2, varscan2
- TRIM3 | c.159G>C p.Q53H | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0.009); catalogued as rs775716378, COSV61983681; called by muse, mutect2, varscan2
- TRIM5 | c.1481G>C p.*494Sext*50 | Nonstop Mutation (SNP) | VAF 24/104 reads (23%) | catalogued as rs772811318, COSV59899527; called by muse, mutect2, varscan2
- TRIOBP | c.3155C>A p.P1052H | Missense Mutation (SNP) | VAF 111/229 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.751); catalogued as COSV60376453; called by muse, mutect2, varscan2
- TRIP10 | c.932G>C p.R311P | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.754); catalogued as COSV57569693; called by muse, mutect2, varscan2
- TRMT1 | c.346G>T p.V116F | Missense Mutation (SNP) | VAF 206/677 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.87); catalogued as COSV52834457; called by muse, mutect2, varscan2
- TSGA10 | c.1634C>A p.S545Y | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV61823003; called by muse, mutect2, varscan2
- TUT7 | c.494C>T p.T165M | Missense Mutation (SNP) | VAF 53/335 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1020835849, COSV52895245; called by muse, mutect2, varscan2
- USH2A | c.14090T>C p.F4697S | Missense Mutation (SNP) | VAF 146/414 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV56358929; called by muse, varscan2
- UTP20 | c.1591C>G p.L531V | Missense Mutation (SNP) | VAF 227/549 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.116); catalogued as COSV55375720; called by muse, mutect2, varscan2
- VEPH1 | c.1905G>C p.Q635H | Missense Mutation (SNP) | VAF 60/279 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.416); catalogued as COSV62877231, COSV62878218; called by muse, mutect2, varscan2
- VPS35L | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); catalogued as COSV51981768; called by muse, mutect2, varscan2
- VPS39 | c.331G>A p.V111I (on ENST00000348544 / NM_001301138.2; = p.V100I on NM_015289.5) | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV58789035; called by muse, mutect2, varscan2
- WDR17 | c.133G>A p.V45I | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV54572370, COSV99706644; called by muse, mutect2, varscan2
- WNK1 | c.515T>A p.V172E | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60031246; called by muse, mutect2, varscan2
- WWC2 | c.1736A>G p.H579R | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV66713231; called by muse, mutect2, varscan2
- ZC3H18 | c.1787G>T p.R596L | Missense Mutation (SNP) | VAF 70/109 reads (64%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.321); catalogued as COSV56324181, COSV56328040; called by muse, mutect2, varscan2
- ZHX2 | c.866A>T p.Q289L | Missense Mutation (SNP) | VAF 116/255 reads (45%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV100072448, COSV58712457; called by muse, mutect2, varscan2
- ZNF254 | c.703G>C p.E235Q | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.242); catalogued as COSV61641995; called by muse, mutect2, varscan2
- ZNF266 | c.188C>G p.S63C | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV63221970, COSV63223384; called by muse, mutect2, varscan2
- ZNF573 | c.1401G>C p.K467N (on ENST00000536220 / NM_001172692.1; = p.K409N on NM_152360.3) | Missense Mutation (SNP) | VAF 48/267 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV59824945; called by muse, mutect2, varscan2
- ZNF77 | c.515G>A p.S172N | Missense Mutation (SNP) | VAF 61/163 reads (37%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.514); catalogued as COSV58821726; called by muse, mutect2, varscan2
- ZNFX1 | c.5203G>C p.E1735Q | Missense Mutation (SNP) | VAF 113/278 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs559641061, COSV65596484; called by muse, mutect2, varscan2
- ZSWIM4 | c.371G>A p.G124E | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV54321115; called by muse, mutect2, varscan2
- ZWILCH | c.22G>T p.A8S | Missense Mutation (SNP) | VAF 45/240 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as COSV57179411; called by muse, mutect2, varscan2
- ZZZ3 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 79/388 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.186); catalogued as rs1381445786, COSV66232339; called by muse, mutect2, varscan2
- AGTPBP1 | c.1048_1059del p.T350_V353del (on ENST00000357081 / NM_001330701.2; = p.T310_V313del on NM_015239.2) | In Frame Del (DEL) | VAF 10/38 reads (26%) | called by mutect2, varscan2
- ARHGEF2 | c.2013del p.P672Qfs*7 (on ENST00000361247 / NM_001162383.2; = p.P644Qfs*7 on NM_004723.3 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 19/118 reads (16%) | called by mutect2, pindel, varscan2
- C9orf131 | c.2007_2018del p.D670_A673del | In Frame Del (DEL) | VAF 28/188 reads (15%) | called by mutect2, pindel, varscan2
- CSNK1G3 | c.112_114del p.M38del | In Frame Del (DEL) | VAF 17/83 reads (20%) | called by pindel*, varscan2
- CYP24A1 | c.1061del p.K354Rfs*18 | Frame Shift Del (DEL) | VAF 59/283 reads (21%) | called by mutect2, pindel, varscan2
- DENND2B | c.2455_2456del p.R819Wfs*38 | Frame Shift Del (DEL) | VAF 16/89 reads (18%) | called by mutect2, pindel, varscan2
- DHX15 | c.2060_2071del p.I687_R690del | In Frame Del (DEL) | VAF 97/362 reads (27%) | called by mutect2, pindel, varscan2
- FXR2 | c.301-1_302delinsTTTTA p.X101_splice | Splice Site (INS) | VAF 7/56 reads (13%) | called by pindel, varscan2*
- IGKV1-9 | c.261T>A p.S87R | Missense Mutation (SNP) | VAF 145/323 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- ITGA2B | c.359_375del p.A120Gfs*26 | Frame Shift Del (DEL) | VAF 5/35 reads (14%) | called by mutect2, pindel
- LILRB3 | c.260C>A p.S87Y | Missense Mutation (SNP) | VAF 82/735 reads (11%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.917); called by muse, varscan2
- NFAT5 | c.3182dup p.L1061Ffs*35 | Frame Shift Ins (INS) | VAF 117/404 reads (29%) | called by mutect2, pindel, varscan2
- NFAT5 | c.4481_4501del p.Q1494_P1500del | In Frame Del (DEL) | VAF 53/207 reads (26%) | called by mutect2, pindel, varscan2
- ORAI1 | c.493dup p.H165Pfs*2 | Frame Shift Ins (INS) | VAF 27/77 reads (35%) | called by mutect2, pindel, varscan2
- SERPINB11 | c.862del p.R288Dfs*10 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | called by mutect2, varscan2
- SMPD4 | c.1497del p.K500Sfs*21 (on ENST00000409031 / NM_017951.4; = p.K471Sfs*21 on NM_017751.4) | Frame Shift Del (DEL) | VAF 42/134 reads (31%) | called by mutect2, pindel, varscan2
- TASP1 | c.1174_1187del p.H392Sfs*41 | Frame Shift Del (DEL) | VAF 9/60 reads (15%) | called by mutect2, pindel, varscan2
- UFL1 | c.1041_1049del p.R347_F349del | In Frame Del (DEL) | VAF 16/64 reads (25%) | called by mutect2, pindel, varscan2
- ZBED4 | c.3287_3289delinsT p.H1096Lfs*3 | Frame Shift Del (DEL) | VAF 43/102 reads (42%) | called by pindel, varscan2*
- ZNF521 | c.688_717del p.G230_D239del | In Frame Del (DEL) | VAF 24/192 reads (13%) | called by mutect2, pindel
- ACVR1C | c.582G>T p.T194= | Silent (SNP) | VAF 39/187 reads (21%) | catalogued as COSV54645623, COSV99694642; called by muse, mutect2, varscan2
- ADCY10 | c.1272T>A p.I424= | Silent (SNP) | VAF 55/183 reads (30%) | catalogued as COSV63240121; called by muse, mutect2, varscan2
- AL645922.1 | c.1116C>A p.P372= | Silent (SNP) | VAF 34/144 reads (24%) | catalogued as COSV100190503, COSV100191100; called by muse, mutect2, varscan2
- ALDH3B1 | c.411G>A p.L137= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs1169794909, COSV50287838; called by muse, mutect2, varscan2
- AP3B1 | c.2778A>T p.I926= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV54882002; called by muse, varscan2
- ATP2B3 | c.2475C>T p.I825= | Silent (SNP) | VAF 162/206 reads (79%) | catalogued as COSV54845027; called by muse, mutect2, varscan2
- B4GALT1 | c.483G>C p.V161= | Silent (SNP) | VAF 19/127 reads (15%) | catalogued as COSV65707918; called by muse, mutect2, varscan2
- CASP7 | c.564G>C p.G188= | Silent (SNP) | VAF 27/151 reads (18%) | catalogued as COSV61881596; called by muse, mutect2, varscan2
- CD34 | c.114T>A p.T38= | Silent (SNP) | VAF 23/161 reads (14%) | catalogued as COSV60412627; called by muse, mutect2, varscan2
- CILP | c.1626G>T p.V542= | Silent (SNP) | VAF 40/100 reads (40%) | catalogued as COSV56023439; called by muse, mutect2, varscan2
- CYP4F2 | c.768C>T p.F256= | Silent (SNP) | VAF 51/316 reads (16%) | catalogued as COSV50000937; called by muse, mutect2, varscan2
- DGUOK | c.111G>T p.G37= | Silent (SNP) | VAF 62/164 reads (38%) | catalogued as COSV51203504; called by muse, mutect2, varscan2
- DNAH12 | c.837T>G p.G279= | Silent (SNP) | VAF 62/223 reads (28%) | catalogued as COSV60856612; called by muse, mutect2, varscan2
- DNAJC27 | c.699C>G p.V233= | Silent (SNP) | VAF 25/149 reads (17%) | catalogued as COSV53094928; called by muse, mutect2, varscan2
- ERMARD | c.1218G>A p.L406= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV100824543, COSV64647986; called by muse, mutect2, varscan2
- FAAH2 | c.48G>C p.A16= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV66507024; called by muse, mutect2, varscan2
- GAB1 | c.2079G>C p.V693= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as COSV53756014; called by muse, mutect2, varscan2
- GABRG2 | c.1377C>T p.C459= (on ENST00000361925 / NM_001375343.1; = p.C419= on NM_000816.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 136/216 reads (63%) | catalogued as COSV62717379; called by muse, mutect2, varscan2
- GBF1 | c.5148A>G p.E1716= (on ENST00000369983 / NM_001377137.1; = p.E1715= on NM_004193.3) | Silent (SNP) | VAF 162/606 reads (27%) | catalogued as COSV64142489; called by muse, mutect2, varscan2
- GJC1 | c.99C>T p.I33= | Silent (SNP) | VAF 25/127 reads (20%) | catalogued as rs1293553169, COSV57911072; called by muse, mutect2, varscan2
- GPR182 | c.1023G>A p.K341= | Silent (SNP) | VAF 62/316 reads (20%) | catalogued as COSV55626001; called by muse, mutect2, varscan2
- GTF3C4 | c.819T>C p.S273= | Silent (SNP) | VAF 207/285 reads (73%) | catalogued as COSV64645236; called by muse, mutect2, varscan2
- H2AZ2 | c.363G>A p.K121= | Silent (SNP) | VAF 20/97 reads (21%) | catalogued as COSV56062298; called by muse, mutect2, varscan2
- HLCS | c.588T>A p.I196= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as COSV60792818; called by muse, mutect2, varscan2
- IL19 | c.159C>T p.T53= | Silent (SNP) | VAF 72/228 reads (32%) | catalogued as COSV54283319; called by muse, mutect2, varscan2
- IRF4 | c.804G>A p.T268= | Silent (SNP) | VAF 62/96 reads (65%) | catalogued as rs769596072, COSV66704996; called by muse, mutect2, varscan2
- IVD | c.759C>A p.T253= (on ENST00000651168; = p.T250= on NM_002225.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as COSV51099014; called by muse, mutect2, varscan2
- KRTAP5-6 | c.213C>A p.G71= | Silent (SNP) | VAF 63/212 reads (30%) | catalogued as COSV66289186; called by muse, mutect2, varscan2
- KSR1 | c.1365A>T p.T455= (on ENST00000644974 / NM_001367810.1; = p.T318= on NM_014238.2) | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV52031235; called by muse, mutect2, varscan2
- L1CAM | c.2106G>T p.P702= | Silent (SNP) | VAF 189/240 reads (79%) | catalogued as COSV62827812; called by muse, mutect2, varscan2
- LARP7 | c.1092A>G p.K364= | Silent (SNP) | VAF 25/45 reads (56%) | catalogued as COSV60520719; called by muse, mutect2, varscan2
- LPCAT1 | c.771C>T p.I257= | Silent (SNP) | VAF 18/170 reads (11%) | catalogued as COSV52037023; called by muse, mutect2, varscan2
- MAP3K5 | c.1314C>G p.L438= | Silent (SNP) | VAF 34/160 reads (21%) | catalogued as COSV62888749; called by muse, mutect2, varscan2
- MORC1 | c.684G>A p.L228= | Silent (SNP) | VAF 48/141 reads (34%) | catalogued as COSV51718397; called by muse, mutect2, varscan2
- MTUS1 | c.1821C>G p.A607= | Silent (SNP) | VAF 95/585 reads (16%) | catalogued as rs375815032, COSV50550554, COSV50554803; called by muse, mutect2, varscan2
- MUC16 | c.18783G>A p.K6261= | Silent (SNP) | VAF 36/188 reads (19%) | catalogued as COSV67461226; called by muse, mutect2, varscan2
- MUC4 | c.14883G>A p.V4961= (on ENST00000463781 / NM_018406.7; = p.V725= on NM_004532.6) | Silent (SNP) | VAF 120/922 reads (13%) | catalogued as COSV57777391; called by muse, mutect2, varscan2
- MYO1H | c.532A>C p.R178= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV60444961; called by muse, mutect2
- NAV1 | c.3114G>A p.E1038= | Silent (SNP) | VAF 74/270 reads (27%) | catalogued as COSV55216726; called by muse, mutect2, varscan2
- NCOA1 | c.2304G>T p.L768= | Silent (SNP) | VAF 37/101 reads (37%) | catalogued as COSV56042571; called by muse, mutect2, varscan2
- NLRC3 | c.2910G>A p.L970= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs780123823, COSV57089875; called by muse, mutect2
- OBSL1 | c.912C>G p.L304= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV54717485; called by muse, mutect2, varscan2
- OR2F2 | c.222C>A p.A74= | Silent (SNP) | VAF 98/812 reads (12%) | catalogued as COSV101283808, COSV68832726; called by muse, varscan2
- OR52A5 | c.492C>A p.L164= | Silent (SNP) | VAF 35/143 reads (24%) | catalogued as COSV56614944; called by muse, mutect2, varscan2
- OR52J3 | c.840C>A p.L280= | Silent (SNP) | VAF 56/233 reads (24%) | catalogued as COSV66746798; called by muse, mutect2, varscan2
- PCDHA8 | c.223C>T p.L75= | Silent (SNP) | VAF 92/416 reads (22%) | catalogued as COSV65336278; called by muse, mutect2, varscan2
- PCDHB7 | c.1893C>T p.S631= | Silent (SNP) | VAF 53/498 reads (11%) | catalogued as rs781839893, COSV50762936; called by muse, varscan2
- PCDHGC4 | c.831C>T p.V277= | Silent (SNP) | VAF 36/182 reads (20%) | catalogued as COSV52749638; called by muse, mutect2, varscan2
- PGLYRP4 | c.204C>T p.C68= | Silent (SNP) | VAF 121/302 reads (40%) | catalogued as COSV62835083; called by muse, mutect2, varscan2
- PIWIL1 | c.477G>A p.K159= | Silent (SNP) | VAF 90/144 reads (63%) | catalogued as COSV55346013; called by muse, mutect2, varscan2
- POLR3GL | c.108G>A p.Q36= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV65215379; called by muse, mutect2, varscan2
- PPM1E | c.1320C>A p.T440= | Silent (SNP) | VAF 47/113 reads (42%) | catalogued as rs151205066, COSV57573188; called by muse, mutect2, varscan2
- PRAM1 | c.651G>A p.A217= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as rs900018925, COSV55313216; called by muse, mutect2, varscan2
- PRX | c.507C>T p.G169= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV52529451, COSV52534446; called by muse, mutect2, varscan2
- PSME3IP1 | c.729C>A p.S243= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV58429036; called by muse, mutect2, varscan2
- PTPRM | c.1785A>T p.T595= | Silent (SNP) | VAF 38/345 reads (11%) | catalogued as COSV59854997; called by muse, mutect2
- RAP2A | c.123C>T p.R41= | Silent (SNP) | VAF 27/131 reads (21%) | catalogued as COSV55354868; called by muse, mutect2, varscan2
- RELT | c.843C>G p.L281= | Silent (SNP) | VAF 85/144 reads (59%) | catalogued as COSV50361234; called by muse, mutect2, varscan2
- RP1 | c.2532T>A p.S844= | Silent (SNP) | VAF 47/115 reads (41%) | catalogued as COSV55115091; called by muse, mutect2, varscan2
- RPL3 | c.1113C>T p.T371= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs376619725, COSV53365148; called by muse, mutect2, varscan2
- SEPTIN10 | c.825C>G p.V275= | Silent (SNP) | VAF 93/510 reads (18%) | catalogued as COSV61780014; called by muse, mutect2, varscan2
- SHANK1 | c.6024G>A p.E2008= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV53248224; called by muse, mutect2, varscan2
- SHISA2 | c.399C>A p.S133= | Silent (SNP) | VAF 31/65 reads (48%) | catalogued as COSV60110598; called by muse, mutect2, varscan2
- SIT1 | c.267G>A p.L89= | Silent (SNP) | VAF 24/169 reads (14%) | catalogued as rs1169261703, COSV52399821; called by muse, mutect2, varscan2
- SLC12A2 | c.693C>A p.A231= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV52470577; called by muse, mutect2, varscan2
- SLC26A7 | c.1722G>T p.L574= | Silent (SNP) | VAF 107/390 reads (27%) | catalogued as COSV52591342; called by muse, mutect2, varscan2
- SLC30A3 | c.678C>A p.P226= | Silent (SNP) | VAF 23/90 reads (26%) | catalogued as COSV51985061; called by muse, mutect2, varscan2
- SLC45A3 | c.498C>T p.F166= | Silent (SNP) | VAF 8/108 reads (7%) | catalogued as COSV65654847; called by muse, mutect2
- SLC6A3 | c.615C>T p.N205= | Silent (SNP) | VAF 22/247 reads (9%) | catalogued as rs764540812, COSV54362848; ClinVar: likely benign; called by muse, mutect2
- SPATA31D1 | c.3252T>C p.D1084= | Silent (SNP) | VAF 19/124 reads (15%) | catalogued as COSV61194966; called by muse, mutect2, varscan2
- SPEN | c.3699C>A p.V1233= | Silent (SNP) | VAF 42/125 reads (34%) | catalogued as COSV65360830; called by muse, mutect2, varscan2
- TAS2R42 | c.411T>C p.S137= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as rs1024803097, COSV62084524; called by muse, mutect2, varscan2
- TET2 | c.324G>A p.Q108= | Silent (SNP) | VAF 26/96 reads (27%) | catalogued as COSV54407515; called by muse, mutect2, varscan2
- TOR1AIP2 | c.1371C>G p.V457= | Silent (SNP) | VAF 47/262 reads (18%) | catalogued as COSV62625937; called by muse, mutect2, varscan2
- TSPY2 | c.90G>C p.V30= | Silent (SNP) | VAF 21/35 reads (60%) | catalogued as COSV100289189; called by muse, mutect2, varscan2
- TTN | c.64206C>T p.P21402= (on ENST00000591111; = p.P13978= on NM_003319.4) | Silent (SNP) | VAF 22/92 reads (24%) | catalogued as rs786205332, COSV60000868; ClinVar: benign; called by muse, mutect2, varscan2
- TTN | c.2520C>A p.A840= (on ENST00000591111; = p.A794= on NM_003319.4) | Silent (SNP) | VAF 74/164 reads (45%) | catalogued as COSV60000999; called by muse, mutect2, varscan2
- TUBD1 | c.705G>A p.L235= | Silent (SNP) | VAF 89/254 reads (35%) | catalogued as COSV57872631; called by muse, mutect2, varscan2
- WDR46 | c.1027T>C p.L343= | Silent (SNP) | VAF 62/215 reads (29%) | catalogued as COSV65842199; called by muse, mutect2
- WWTR1 | c.132G>T p.R44= | Silent (SNP) | VAF 29/43 reads (67%) | catalogued as COSV62291114; called by muse, mutect2, varscan2
- XIRP2 | c.9255G>A p.E3085= (on ENST00000628543; = p.E3260= on NM_152381.6) | Silent (SNP) | VAF 28/129 reads (22%) | catalogued as rs746756891, COSV54695003, COSV99744299; called by muse, mutect2, varscan2
- XXYLT1 | c.777A>T p.P259= | Silent (SNP) | VAF 55/221 reads (25%) | catalogued as COSV59983102; called by muse, mutect2, varscan2
- ZC3H4 | c.3432C>T p.S1144= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs780922122, COSV53412152; called by muse, mutect2, varscan2
- ZFPM2 | c.672G>T p.L224= | Silent (SNP) | VAF 20/153 reads (13%) | catalogued as COSV65873195, COSV65873395; called by muse, mutect2, varscan2
- ZFPM2 | c.1428C>T p.S476= | Silent (SNP) | VAF 56/303 reads (18%) | catalogued as COSV65873201; called by muse, mutect2, varscan2
- ZNF112 | c.639C>A p.V213= (on ENST00000337401 / NM_001083335.2; = p.V207= on NM_013380.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 117/347 reads (34%) | catalogued as COSV61619740; called by muse, mutect2, varscan2
- ZNF491 | c.408T>C p.C136= | Silent (SNP) | VAF 64/216 reads (30%) | catalogued as COSV60057191; called by muse, mutect2, varscan2
- ARL6IP6 | c.-1C>G | 5'UTR (SNP) | VAF 28/127 reads (22%) | catalogued as COSV100424001; called by muse, mutect2, varscan2
- C12orf76 | n.674G>A | RNA (SNP) | VAF 23/95 reads (24%) | catalogued as COSV55676052; called by muse, mutect2, varscan2
- C3orf52 | c.468-94C>G | Intron (SNP) | VAF 6/38 reads (16%) | catalogued as COSV53495357; called by muse, mutect2
- FABP5P3 | chr7:152445783 G>T | 3'Flank (SNP) | VAF 69/142 reads (49%) | called by muse, mutect2, varscan2
- GRIK2 | c.2563-4346A>C | Intron (SNP) | VAF 13/70 reads (19%) | catalogued as COSV100026109; called by muse, mutect2, varscan2
- KIR3DL2 | chr19:54847209 G>C | 5'Flank (SNP) | VAF 107/1011 reads (11%) | called by muse, varscan2
- PDE7A | c.139-6056A>T | Intron (SNP) | VAF 35/199 reads (18%) | catalogued as COSV101052661; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-23878T>A | Intron (SNP) | VAF 57/225 reads (25%) | catalogued as COSV67442969; called by muse, mutect2, varscan2
- SNORD116-26 | n.72G>T | RNA (SNP) | VAF 20/158 reads (13%) | called by muse, mutect2, varscan2
- SSPOP | n.6881C>G | RNA (SNP) | VAF 114/534 reads (21%) | catalogued as rs113524670, COSV50487190; called by muse, mutect2, varscan2
- TSR1 | c.1770+147G>C | Intron (SNP) | VAF 28/115 reads (24%) | catalogued as rs751793771, COSV100027008; called by muse, mutect2, varscan2
- TTN | c.10360+4057C>T | Intron (SNP) | VAF 28/168 reads (17%) | catalogued as COSV60000951; called by muse, mutect2, varscan2
